Somatic mutation profile of tumor specimen TCGA-55-6970-01A (aliquot TCGA-55-6970-01A-11D-1945-08) from TCGA case TCGA-55-6970, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 67.8 years (24,773 days).
Specimen TCGA-55-6970-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc6315e3-b3cf-4474-8335-cb98e500833e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6970-11A (Solid Tissue Normal), aliquot TCGA-55-6970-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a97a7f5f-1cfb-475e-93f3-aef0583da7ea

The open-access MAF lists 184 somatic variants for this specimen: 148 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 32, Nonsense Mutation 15, Splice Site 6, Frame Shift Del 3, Intron 2, Frame Shift Ins 1, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA13 | c.14477G>T p.R4826L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs771175690, COSV104435684, COSV68942945; called by muse, varscan2
- ABCB5 | c.115T>C p.F39L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV68854674; called by muse, mutect2, varscan2
- ABCD4 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs201744101, COSV100084027, COSV53990709; called by muse, mutect2, varscan2
- ACTG2 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV61827408; called by muse, mutect2, varscan2
- ADGRL3 | c.3210C>G p.D1070E (on ENST00000506720 / NM_001322402.2; = p.D1002E on NM_015236.6) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV72229131; called by muse, mutect2, varscan2
- ADH1C | c.1102A>T p.S368C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.176); catalogued as COSV72624776; called by muse, mutect2, varscan2
- AGO3 | c.1530G>C p.K510N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV55790752; called by muse, mutect2
- AMER2 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV63435957; called by muse, mutect2, varscan2
- APOE | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs767339630, COSV52984932; called by muse, varscan2
- ARHGAP33 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs187189822, COSV50119313; called by muse, mutect2, varscan2
- ARHGAP4 | c.1503C>A p.N501K | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.393); catalogued as COSV63130627; called by muse, mutect2, varscan2
- ARHGEF1 | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV61526116; called by muse, mutect2, varscan2
- ART4 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV57450873; called by muse, mutect2, varscan2
- ATP10B | c.497G>T p.C166F | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.694); catalogued as COSV58777592; called by muse, mutect2, varscan2
- BRCC3 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57461706; called by muse, mutect2, varscan2
- BTN3A2 | c.172A>G p.M58V | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.983); catalogued as COSV62686695; called by muse, mutect2, varscan2
- C11orf24 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.053); catalogued as COSV58504898; called by muse, mutect2, varscan2
- C7 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57470283; called by muse, mutect2, varscan2
- C9 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV54674076; called by muse, mutect2, varscan2
- CCDC186 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | catalogued as COSV65160542; called by muse, mutect2, varscan2
- CCN3 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558076900, COSV52382956; called by muse, mutect2, varscan2
- CCN4 | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51529246, COSV51529623; called by muse, mutect2, varscan2
- CD163L1 | c.1316C>A p.T439N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.324); catalogued as COSV58010530; called by muse, mutect2, varscan2
- CDH9 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV50251062, COSV50289480; called by muse, mutect2, varscan2
- CDHR2 | c.2750C>A p.T917N | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs753530627, COSV56134288; called by muse, mutect2, varscan2
- CLPTM1L | c.1289C>A p.S430Y | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV57989179; called by muse, mutect2, varscan2
- CLSTN2 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV71717789; called by muse, mutect2, varscan2
- CNKSR1 | c.1846C>T p.L616F (on ENST00000374253 / NM_001297647.2; = p.L609F on NM_006314.3) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs1274689657, COSV58792145; called by muse, mutect2, varscan2
- CNTNAP5 | c.1630T>C p.C544R | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70470672; called by muse, mutect2, varscan2
- COL22A1 | c.2265C>A p.D755E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.847); catalogued as rs141313886, COSV100280375; called by muse, varscan2
- COL4A1 | c.1564G>T p.G522C | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65420755, COSV65425099; called by muse, mutect2, varscan2
- CRYBB3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs375275387; called by mutect2, varscan2
- CTNNA2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.413); catalogued as COSV100785722; called by muse, mutect2, varscan2
- CTSA | c.693G>A p.R231= | Splice Region (SNP) | VAF 19/103 reads (18%) | catalogued as rs762896416, COSV51940422; called by muse, mutect2, varscan2
- CYP17A1 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs753683490, COSV64004685; called by muse, mutect2, varscan2
- DAG1 | c.1195G>C p.G399R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.228); catalogued as COSV58182350; called by muse, mutect2, varscan2
- DNAJC27 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV53093912; called by muse, mutect2, varscan2
- DOCK10 | c.5185C>T p.L1729F | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51346984; called by muse, mutect2
- DOCK10 | c.5128C>T p.H1710Y | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51347013; called by muse, varscan2
- DSCAM | c.1760A>G p.Q587R | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV68020228; called by muse, mutect2, varscan2
- EDA2R | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.286); catalogued as rs1396839003, COSV53630057; called by muse, mutect2, varscan2
- ENTHD1 | c.1611C>A p.D537E | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV57316944; called by muse, mutect2, varscan2
- EPHB6 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV67417156; called by muse, mutect2, varscan2
- ERCC6L | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV57819268; called by muse, mutect2, varscan2
- FAM171B | c.1921G>C p.V641L | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as COSV59000472; called by muse, mutect2, varscan2
- FAM187B | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1181000883, COSV61200855; called by muse, mutect2, varscan2
- FBXO22 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781725457, COSV57616502; called by muse, mutect2, varscan2
- FCRLA | c.1057G>T p.D353Y (on ENST00000367959; = p.D330Y on NM_032738.4) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1181318183, COSV52684129, COSV52686878; called by muse, mutect2, varscan2
- GABRA3 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64794816, COSV64800402; called by muse, mutect2
- GAGE10 | c.66G>T p.M22I | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV68163611; called by muse, mutect2, varscan2
- GALNT6 | c.758G>C p.R253P | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs536166167, COSV62541568; called by muse, mutect2, varscan2
- GZMK | c.323T>A p.V108D | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV50244009; called by muse, mutect2, varscan2
- H1-5 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.264); catalogued as COSV58898818, COSV58898829, COSV58898880; called by muse, mutect2, varscan2
- HCN1 | c.2156A>G p.Y719C | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.945); catalogued as COSV57491858; called by muse, mutect2, varscan2
- HEXA | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV51504992; called by muse, mutect2, varscan2
- ITGB1BP2 | c.817-1G>C p.X273_splice | Splice Site (SNP) | VAF 17/60 reads (28%) | catalogued as COSV52135276; called by muse, mutect2, varscan2
- IVL | c.1666C>A p.Q556K | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.066); catalogued as COSV100908306, COSV64215387; called by muse, mutect2, varscan2
- JMJD1C | c.1301G>A p.W434* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as COSV67857423, COSV67863090; called by muse, mutect2, varscan2
- KCNH1 | c.1463-1G>A p.X488_splice (on ENST00000271751 / NM_172362.3; = p.X461_splice on NM_002238.4) | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as rs1212884808, COSV55068210; called by muse, mutect2, varscan2
- KIF15 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV58158175; called by muse, mutect2, varscan2
- KIF4A | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV65541165; called by muse, mutect2, varscan2
- KLHDC7B | c.1298C>A p.P433Q (on ENST00000395676; = p.P1074Q on NM_138433.5) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1336908042, COSV67464178; called by muse, mutect2, varscan2
- KLHL17 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs370965813; called by muse, mutect2, varscan2
- L1CAM | c.3480G>T p.Q1160H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV62826665; called by muse, mutect2, varscan2
- LEP | c.497G>T p.G166V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.371); catalogued as rs1458700374, COSV58240603; called by muse, mutect2, varscan2
- LIPK | c.353G>A p.S118N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs1487824827, COSV68200557; called by muse, mutect2, varscan2
- LPAR4 | c.179C>A p.S60Y | Missense Mutation (SNP) | VAF 88/275 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV70912150; called by muse, mutect2, varscan2
- LRP1B | c.12466G>C p.D4156H | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.365); catalogued as COSV67183540, COSV67229057, COSV67288949; called by muse, mutect2, varscan2
- LRP1B | c.8923G>T p.G2975C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV67183546; called by muse, mutect2, varscan2
- LRP1B | c.4537C>A p.P1513T | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1322303020, COSV67183549; called by muse, mutect2, varscan2
- LRRFIP2 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60865932; called by muse, mutect2
- LSG1 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.395); catalogued as COSV54568379; called by muse, mutect2, varscan2
- MAGEA8 | c.635T>A p.I212N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54063584; called by muse, mutect2, varscan2
- MAGED2 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV54496833; called by muse, mutect2, varscan2
- MAP3K15 | c.1362C>G p.S454R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV100135479; called by muse, mutect2, varscan2
- MARCHF7 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52027293; called by muse, mutect2, varscan2
- MBNL3 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.298); catalogued as COSV63730141; called by muse, varscan2
- MSLNL | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs1014708007, COSV50099657; called by mutect2, varscan2
- MTMR4 | c.1933G>T p.E645* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV60199162; called by muse, mutect2, varscan2
- NOP2 | c.628C>G p.L210V (on ENST00000322166 / NM_001258308.2; = p.L206V on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV59109242; called by muse, mutect2, varscan2
- NRIP1 | c.1990G>T p.G664C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV59654801; called by mutect2, varscan2
- NXPE4 | c.1000A>G p.T334A (on ENST00000375478 / NM_001077639.2; = p.T50A on NM_017678.3) | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV64943338; called by muse, mutect2, varscan2
- OBSCN | c.3129G>T p.Q1043H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV52737022; called by muse, mutect2, varscan2
- OR14I1 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61198868; called by muse, mutect2, varscan2
- OR2A12 | c.735C>A p.C245* | Nonsense Mutation (SNP) | VAF 64/160 reads (40%) | catalogued as COSV68821012; called by muse, mutect2, varscan2
- OR2AG1 | c.787A>G p.S263G | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as COSV100264966; called by muse, mutect2, varscan2
- OR2T4 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV63543244; called by muse, mutect2
- OR52W1 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.785); catalogued as COSV60950370; called by muse, mutect2, varscan2
- OR5B3 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV58676238; called by muse, mutect2, varscan2
- OR6N1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.541); catalogued as rs1370206573, COSV58647319; called by muse, mutect2
- OR8B12 | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.182); catalogued as COSV60910856; called by muse, mutect2, varscan2
- OSBPL1A | c.806+2T>A p.X269_splice | Splice Site (SNP) | VAF 29/116 reads (25%) | catalogued as COSV60194947; called by muse, mutect2, varscan2
- PARVB | c.865G>T p.V289F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV58683591; called by muse, mutect2, varscan2
- PCDH19 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.668); catalogued as COSV99720606; called by muse, varscan2
- PCNX2 | c.5111G>A p.C1704Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1194780981, COSV50781024; called by muse, mutect2
- PDE6B | c.2504-1G>A p.X835_splice | Splice Site (SNP) | VAF 68/175 reads (39%) | catalogued as COSV55323552; called by muse, mutect2, varscan2
- PGLYRP3 | c.886G>T p.D296Y | Missense Mutation (SNP) | VAF 267/497 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV51948729; called by muse, mutect2, varscan2
- PHKA1 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV59801332; called by muse, mutect2, varscan2
- PIGN | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs1358106061, COSV62947620; called by muse, mutect2, varscan2
- PPP3CB | c.1571A>T p.Q524L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as rs1320067384, COSV55018441; called by muse, mutect2, varscan2
- PTCHD3 | c.903C>A p.F301L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101438801, COSV71256258; called by muse, mutect2, varscan2
- PTER | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.489); catalogued as COSV54344371; called by muse, varscan2
- PYGB | c.661-1G>A p.X221_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV53815381; called by muse, mutect2, varscan2
- REG4 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV56652047; called by muse, mutect2
- RFTN2 | c.582T>A p.C194* | Nonsense Mutation (SNP) | VAF 43/165 reads (26%) | catalogued as COSV54385499; called by muse, mutect2, varscan2
- RYR1 | c.5963C>T p.A1988V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV62087856; called by muse, mutect2, varscan2
- SATB1 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV58667165; called by muse, mutect2, varscan2
- SERPINB3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746360608, COSV52189683; called by muse, mutect2, varscan2
- SETD5 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1177788556, COSV56707127; called by muse, mutect2, varscan2
- SIPA1L1 | c.3440G>C p.R1147P | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs200964349, COSV62168247; called by muse, mutect2, varscan2
- SLC6A7 | c.217+1G>T p.X73_splice | Splice Site (SNP) | VAF 22/100 reads (22%) | catalogued as rs751851815, COSV57936743; called by muse, mutect2, varscan2
- SLC9A4 | c.1907G>A p.R636K | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV54828680; called by muse, mutect2, varscan2
- SLC9A6 | c.946G>T p.V316L | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.025); catalogued as COSV65787194, COSV65788420; called by muse, mutect2, varscan2
- SMARCD1 | c.203G>T p.R68L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.11); catalogued as rs764685953, COSV57315947; called by muse, mutect2, varscan2
- SMARCD1 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1247141490, COSV67411577; called by muse, mutect2, varscan2
- SNTG1 | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs778737467, COSV52423447, COSV99385799; called by muse, mutect2, varscan2
- SNX8 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV56124928; called by muse, varscan2
- SORCS1 | c.3374G>T p.R1125I | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV53839346; called by muse, mutect2, varscan2
- SPATA5 | c.1376G>T p.C459F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99916225; called by muse, mutect2, varscan2
- SPATA5 | c.1377T>A p.C459* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV99916228; called by muse, mutect2, varscan2
- SPTA1 | c.3037G>T p.D1013Y | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63748419; called by muse, mutect2, varscan2
- STK11 | c.749del p.T250Rfs*37 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as COSV100481262; called by mutect2, pindel, varscan2
- TANC2 | c.3127G>T p.G1043* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as rs200323393, COSV67329576; called by muse, mutect2, varscan2
- TBL1X | c.220C>A p.H74N | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54274084; called by muse, mutect2, varscan2
- TDRD5 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs750046375, COSV54238507; called by muse, mutect2, varscan2
- TGM1 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as rs763303938, COSV52861541; called by muse, mutect2, varscan2
- TGS1 | c.706G>T p.E236* | Nonsense Mutation (SNP) | VAF 32/125 reads (26%) | catalogued as COSV52698012; called by muse, mutect2, varscan2
- TSPOAP1 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.771); catalogued as rs772461636, COSV52103309; called by muse, mutect2, varscan2
- TTC21A | c.1521G>T p.L507F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV57182933; called by muse, mutect2, varscan2
- UBR2 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV65767064; called by muse, mutect2, varscan2
- UNC5D | c.2609C>A p.A870D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV54767142, COSV54782209; called by muse, mutect2, varscan2
- USP1 | c.2000G>C p.G667A | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV51994872; called by muse, mutect2, varscan2
- WDR25 | c.896G>T p.R299L | Missense Mutation (SNP) | VAF 79/167 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as COSV58933628; called by muse, mutect2, varscan2
- WDR41 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs375379215; called by mutect2, varscan2
- ZBED8 | c.1490A>C p.E497A | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV68824307; called by muse, mutect2
- ZNF383 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 33/70 reads (47%) | catalogued as COSV61938502; called by muse, mutect2, varscan2
- ZNF43 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV61682669; called by muse, mutect2, varscan2
- ZNF473 | c.1974T>A p.S658R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV54521911; called by muse, mutect2, varscan2
- ZNF674 | c.1390A>T p.T464S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70378521; called by muse, mutect2
- ZNF674 | c.1388A>T p.H463L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70378524; called by muse, mutect2
- ZNF71 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV60146337; called by muse, mutect2, varscan2
- ZNF711 | c.1946G>T p.C649F | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52151109; called by muse, mutect2, varscan2
- GPR149 | c.666del p.P223Rfs*82 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- KEAP1 | c.966_967insT p.K323* | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | called by mutect2, pindel*, varscan2
- MAGEB6B | c.239C>G p.S80* | Nonsense Mutation (SNP) | VAF 27/240 reads (11%) | called by muse, mutect2, varscan2
- OR2L8 | c.438del p.S147Lfs*4 | Frame Shift Del (DEL) | VAF 99/239 reads (41%) | called by mutect2, pindel, varscan2
- TRAJ18 | c.62G>T p.W21L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ADGRG4 | c.7950G>A p.V2650= | Silent (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- ATP2B2 | c.1731C>A p.R577= (on ENST00000352432; = p.R543= on NM_001683.5) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1451127727, COSV59488205; called by muse, mutect2, varscan2
- BNIP2 | c.234G>T p.G78= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1367918114, COSV51104981; called by muse, mutect2, varscan2
- CASC3 | c.414C>T p.T138= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV52865851; called by muse, mutect2, varscan2
- CDH5 | c.1854C>T p.I618= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1386102992, COSV58515631; called by muse, mutect2, varscan2
- CLCN2 | c.1980A>G p.L660= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs546609891, COSV55599031; called by muse, mutect2, varscan2
- DYNAP | c.474G>C p.V158= (on ENST00000321600; = p.V132= on NM_173629.3) | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV58665924; called by muse, mutect2, varscan2
- DYNC1H1 | c.7233C>A p.P2411= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs1360449537, COSV64134152; called by muse, mutect2, varscan2
- FAM124A | c.96G>T p.T32= | Silent (SNP) | VAF 35/121 reads (29%) | catalogued as COSV54474197, COSV54476125; called by muse, mutect2, varscan2
- GABRE | c.1320C>A p.L440= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100944353; called by muse, mutect2, varscan2
- GRM4 | c.1329C>G p.G443= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV65210170; called by muse, mutect2, varscan2
- HCFC1 | c.468C>A p.A156= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV60069191; called by muse, mutect2, varscan2
- KIF4B | c.2920C>A p.R974= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV70527082, COSV70528453; called by muse, mutect2, varscan2
- KIFC2 | c.1023C>T p.A341= | Silent (SNP) | VAF 50/219 reads (23%) | catalogued as COSV56759747; called by muse, mutect2, varscan2
- MAGED1 | c.135C>A p.A45= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV58514405; called by muse, mutect2, varscan2
- MAMLD1 | c.1257G>A p.P419= | Silent (SNP) | VAF 78/271 reads (29%) | catalogued as rs782596241, COSV53371739; called by muse, mutect2, varscan2
- NFX1 | c.2880A>G p.L960= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1472154427, COSV65350811; called by muse, varscan2
- NPAP1 | c.2772A>T p.P924= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV61504038; called by muse, mutect2, varscan2
- NPY2R | c.951C>T p.S317= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV61527126; called by muse, mutect2, varscan2
- OR14I1 | c.141C>A p.I47= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV61198874, COSV61199864; called by muse, mutect2
- OR2AG1 | c.786C>A p.P262= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV100264960; called by muse, mutect2, varscan2
- ORC4 | c.42A>T p.T14= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV51571464; called by muse, mutect2, varscan2
- PCDH17 | c.3450G>T p.R1150= | Silent (SNP) | VAF 60/161 reads (37%) | catalogued as COSV64971464; called by muse, mutect2, varscan2
- PCDH19 | c.120C>T p.A40= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV55257033; called by muse, varscan2
- PEG3 | c.1209G>T p.S403= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV55623768, COSV55626305; called by muse, mutect2, varscan2
- REG3A | c.48C>A p.S16= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV59408204; called by muse, mutect2, varscan2
- RYR3 | c.8922G>A p.K2974= (on ENST00000389232; = p.K2975= on NM_001036.6) | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV66776762, COSV66795354; called by muse, mutect2, varscan2
- SATB2 | c.1116G>A p.L372= | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as COSV53477537; called by muse, mutect2, varscan2
- SLC8A3 | c.447C>A p.L149= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV63518688; called by muse, mutect2, varscan2
- SULT1C3 | c.27C>A p.P9= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs1295523788, COSV61252288; called by muse, mutect2, varscan2
- TIAM1 | c.1338G>A p.L446= | Silent (SNP) | VAF 32/154 reads (21%) | catalogued as COSV54536334; called by muse, mutect2, varscan2
- ZNF623 | c.1092G>A p.Q364= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV71697071; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822767 C>A | 5'Flank (SNP) | VAF 15/61 reads (25%) | catalogued as rs1468376809; called by muse, mutect2, varscan2
- LAMP2 | c.1093+2532G>A | Intron (SNP) | VAF 11/129 reads (9%) | catalogued as rs730880488, COSV52354939; ClinVar: uncertain significance; called by muse, mutect2
- POLA1 | c.2947-21311G>A | Intron (SNP) | VAF 30/203 reads (15%) | catalogued as rs1370942836, COSV66891326; called by muse, mutect2, varscan2
- ZNF99 | c.*680G>A | 3'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as rs1480899591, COSV68054619; called by muse, varscan2
